Somatic mutation profile of tumor specimen TCGA-AG-3887-01A (aliquot TCGA-AG-3887-01A-01W-1073-09) from TCGA case TCGA-AG-3887, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.3 years (24,960 days).
Specimen TCGA-AG-3887-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0059073f-5d4e-418c-8c30-5c3319eabdc9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3887-10A (Blood Derived Normal), aliquot TCGA-AG-3887-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3380ad9-ef6b-4b18-b669-d7e0810b2414

The open-access MAF lists 79 somatic variants for this specimen: 64 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 14, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, Frame Shift Ins 1, RNA 1, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 27/45 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 46/99 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1057519872, COSV55911123; ClinVar: not provided; called by muse, mutect2, varscan2
- SMAD4 | c.1610A>T p.D537V | Missense Mutation (SNP) | VAF 65/87 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61684111, COSV61685387, COSV61697211; called by muse, mutect2, varscan2
- ADAMTS16 | c.2279-1G>C p.X760_splice | Splice Site (SNP) | VAF 18/278 reads (6%) | catalogued as COSV56983043, COSV57005224; called by muse, mutect2
- AKAP6 | c.3049C>T p.L1017F | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55228777; called by muse, mutect2, varscan2
- ANKRD28 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as COSV101080696; called by muse, mutect2
- APC | c.3778C>T p.Q1260* | Nonsense Mutation (SNP) | VAF 64/127 reads (50%) | catalogued as CD941589, COSV57348518; called by muse, mutect2, varscan2
- ARHGAP15 | c.683C>A p.P228Q | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV54515643; called by muse, mutect2, varscan2
- ARHGAP5 | c.2669A>T p.D890V | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV61538704; called by muse, mutect2, varscan2
- ATP10A | c.1744G>T p.V582F | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63522285; called by muse, mutect2, varscan2
- BAG3 | c.1618G>A p.G540R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.274); catalogued as COSV100958240; called by muse, mutect2
- BCL2A1 | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 98/270 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV51213765; called by muse, mutect2, varscan2
- CEMIP | c.3017T>C p.I1006T | Missense Mutation (SNP) | VAF 136/320 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV54998749; called by muse, mutect2, varscan2
- CHST8 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as rs761058926, COSV52858907, COSV52862302; called by muse, mutect2, varscan2
- CILP2 | c.2500G>A p.V834I | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs1254400933, COSV52275905; called by muse, mutect2, varscan2
- COL4A1 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as rs369960952, COSV65429741; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- DENND2D | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV62959239; called by muse, mutect2, varscan2
- EFR3A | c.1830G>C p.Q610H | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); catalogued as COSV54461437; called by muse, mutect2
- ELL | c.294del p.Q98Hfs*99 | Frame Shift Del (DEL) | VAF 7/10 reads (70%) | catalogued as COSV53215265; called by mutect2, varscan2
- ESM1 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); catalogued as rs367904025; called by muse, mutect2, varscan2
- FIGN | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as rs761484365, COSV60765386; called by muse, mutect2, varscan2
- FRMPD4 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 170/196 reads (87%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.937); catalogued as COSV66221502; called by muse, mutect2, varscan2
- GALNT12 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 8/246 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs912533623, COSV100899149; ClinVar: uncertain significance; called by muse, mutect2
- GPI | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs370578920; called by muse, mutect2, varscan2
- GRHPR | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV58944667, COSV58944808; called by muse, mutect2, varscan2
- HDC | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751827833, COSV51078265; called by muse, mutect2, varscan2
- IL17RC | c.1505T>A p.L502H (on ENST00000295981 / NM_153461.4; = p.L416H on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV55974695; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1940C>T p.T647M | Missense Mutation (SNP) | VAF 79/98 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as rs367966545, COSV100780682, COSV61160689; called by muse, mutect2, varscan2
- IL1RN | c.365G>A p.R122H (on ENST00000409930 / NM_173842.3; = p.R104H on NM_000577.5) | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373101669; called by muse, mutect2
- MAD1L1 | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56244912; called by muse, mutect2, varscan2
- MCAM | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs200709459, COSV50632434; called by muse, mutect2
- NDUFA9 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 190/342 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56931494; called by muse, mutect2, varscan2
- OR10G7 | c.824A>G p.Y275C | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); catalogued as COSV57868488; called by muse, mutect2, varscan2
- OR11H1 | c.613A>C p.T205P | Missense Mutation (SNP) | VAF 83/257 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV99421832; called by muse, mutect2, varscan2
- OR2L3 | c.107T>C p.M36T | Missense Mutation (SNP) | VAF 550/660 reads (83%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV63456066; called by muse, mutect2, varscan2
- PACS1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs760699901, COSV57696399; called by muse, mutect2, varscan2
- PAX1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.713); catalogued as COSV68272398; called by muse, mutect2, varscan2
- PCDHB15 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as rs1201476325, COSV51300154; called by muse, mutect2, varscan2
- POLE2 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV53561510; called by muse, mutect2, varscan2
- POTEH | c.372C>G p.D124E | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as COSV100624993, COSV58882058, COSV58886966; called by muse, mutect2, varscan2
- PRKD3 | c.1886A>G p.N629S | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.017); catalogued as COSV52216954; called by muse, mutect2, varscan2
- PTHLH | c.107G>C p.R36T | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV52369202; called by muse, mutect2, varscan2
- PXDNL | c.3935C>T p.T1312M | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs780135369, COSV62478598; called by muse, mutect2, varscan2
- RAB11A | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.822); catalogued as COSV56041514; called by muse, mutect2
- RBX1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV53430854; called by muse, mutect2, varscan2
- RNF168 | c.1338C>G p.D446E | Missense Mutation (SNP) | VAF 89/201 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV58839218; called by muse, mutect2, varscan2
- RYR1 | c.7013C>A p.A2338D | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV62107481; called by muse, mutect2, varscan2
- SAE1 | c.387G>T p.V129= | Splice Region (SNP) | VAF 150/322 reads (47%) | catalogued as COSV54298196; called by muse, mutect2, varscan2
- SALL1 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057523061, COSV51758602; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN1A | c.2110C>A p.L704I (on ENST00000303395 / NM_001202435.3; = p.L693I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV57683238; called by muse, mutect2, varscan2
- SGPP1 | c.1039C>G p.L347V | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.138); catalogued as rs781255345, COSV55976350; called by muse, mutect2, varscan2
- TLDC2 | c.95_97dup p.E32dup | In Frame Ins (INS) | VAF 10/41 reads (24%) | catalogued as rs1304913834; called by mutect2, varscan2
- TMEM132B | c.3234G>T p.M1078I | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as COSV54766007; called by muse, mutect2, varscan2
- TRPV1 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs1340972739; called by muse, mutect2, varscan2
- TTN | c.83404C>T p.P27802S (on ENST00000591111; = p.P20378S on NM_003319.4) | Missense Mutation (SNP) | VAF 37/85 reads (44%) | PolyPhen probably damaging (0.998); catalogued as COSV60278573; called by muse, mutect2, varscan2
- TXNRD1 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.251); catalogued as rs769989720, COSV71220598; called by muse, mutect2, varscan2
- UGGT2 | c.2575T>C p.F859L | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV65078308; called by muse, mutect2, varscan2
- VTN | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201545006, COSV52648005; called by muse, mutect2, varscan2
- ZBED6CL | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV59605269; called by muse, mutect2, varscan2
- ZNF608 | c.3946C>T p.R1316* | Nonsense Mutation (SNP) | VAF 66/148 reads (45%) | catalogued as COSV60434911; called by muse, mutect2, varscan2
- APC | c.3928_3929del p.K1310Dfs*4 | Frame Shift Del (DEL) | VAF 39/133 reads (29%) | called by mutect2, pindel, varscan2
- DUOX1 | c.3576_3585del p.X1192_splice | Splice Site (DEL) | VAF 30/104 reads (29%) | called by mutect2, pindel, varscan2
- FAT4 | c.12686dup p.Y4229* | Nonsense Mutation (INS) | VAF 22/78 reads (28%) | called by mutect2, pindel, varscan2
- PDE4DIP | c.4307dup p.D1437Gfs*27 | Frame Shift Ins (INS) | VAF 40/122 reads (33%) | called by mutect2, varscan2
- ACO1 | c.207G>A p.T69= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as rs751872663, COSV59376709; called by muse, mutect2, varscan2
- ANGPT1 | c.174G>T p.T58= | Silent (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2, varscan2
- CLK4 | c.1344G>T p.L448= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV60320571; called by muse, mutect2, varscan2
- FAP | c.1302A>T p.P434= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV51866413; called by muse, mutect2, varscan2
- FIS1 | c.249G>T p.R83= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV56191950; called by muse, mutect2, varscan2
- HOXC9 | c.222C>T p.S74= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs34136736; called by muse, mutect2, varscan2
- KCNMB1 | c.456C>T p.Y152= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs145466654; called by muse, mutect2
- L2HGDH | c.978G>A p.G326= | Silent (SNP) | VAF 85/207 reads (41%) | catalogued as COSV55559989; called by muse, mutect2, varscan2
- LAPTM4B | c.933G>A p.P311= (on ENST00000445593; = p.P220= on NM_018407.6) | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs754566573, COSV71454756; called by muse, mutect2, varscan2
- PRG3 | c.402C>A p.G134= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV54664449; called by muse, mutect2, varscan2
- ROBO3 | c.1077T>A p.A359= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV67302387; called by muse, mutect2, varscan2
- SOBP | c.852A>G p.E284= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV58001906; called by muse, mutect2, varscan2
- SYNE1 | c.8403C>T p.Y2801= (on ENST00000367255 / NM_182961.4; = p.Y2808= on NM_033071.3) | Silent (SNP) | VAF 52/134 reads (39%) | catalogued as rs757104773, COSV54898013; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- SYT6 | c.477G>T p.L159= (on ENST00000610222 / NM_001366225.1; = p.L74= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV65775661; called by muse, mutect2, varscan2
- DCHS2 | n.7841G>A | RNA (SNP) | VAF 58/144 reads (40%) | catalogued as rs61741036; called by muse, mutect2, varscan2
